CGCI case HTMCP-03-06-02170 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/981300da-9136-402a-88df-2c76b1e3ad87

Demographics
Sex at birth: female; Race: black or african american; Age at index: 42 years; Vital status: Dead; Days to death: 375 days (1.0 years).

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 375 days (1.0 years).
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1 day; Disease response: With Tumor.
- Days to follow up: 23 days; Disease response: With Tumor.
- Days to follow up: 375 days (1.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 47.8 kg; Height: 163 cm; BMI: 18; CD4 count: 364; Haart treatment indicator: Yes; HIV viral load: 0; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02170-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02170-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Days from index date to last known alive: 1; Tumor status: With tumor; Live birth pregnancy count: 10; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 10; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Keratinizing; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2010; HIV rna load at diagnosis: 0; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation treatment reason not completed other: Patient did not return for follow up appointment.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: No Treatment.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02170-01A-01R-6194:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02170-01A-01D-6194:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02170-10A-01D-6194:
- % tumour top: 0
- % tumour bottom: 0
